CCDI case PBCGWB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/c0bf3e3a-296d-46c0-8f56-06a0003a6c9a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Small cell carcinoma, NOS: ICD-O-3 morphology code: 8041/3; Tissue or organ of origin: Ovary; Age at diagnosis: 15.5 years (5,662 days).

Biospecimens (3 samples)
- Sample 0DRU3O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRU3U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSEKH: Tissue type: Tumor; Specimen type: Solid Tissue.
